Somatic mutation profile of tumor specimen TCGA-SH-A9CU-01A (aliquot TCGA-SH-A9CU-01A-11D-A39R-32) from TCGA case TCGA-SH-A9CU, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.6 years (22,135 days).
Specimen TCGA-SH-A9CU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 612a9d4e-bed8-46c1-a8ee-5b8104508cdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SH-A9CU-10A (Blood Derived Normal), aliquot TCGA-SH-A9CU-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72001bf6-c4c0-4186-b42d-db43c8654f52

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, 3'UTR 2, Frame Shift Del 1, In Frame Del 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4663G>A p.A1555T | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.045); catalogued as rs1369396308; called by muse, mutect2, varscan2
- BTNL8 | c.1021C>T p.H341Y | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs763420925, COSV51460590, COSV51462320; called by muse, mutect2, varscan2
- GANAB | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1414733599, COSV60466555; called by muse, mutect2, varscan2
- HELLS | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53294943; called by muse, mutect2, varscan2
- HMCN1 | c.970del p.S324Lfs*36 | Frame Shift Del (DEL) | VAF 33/79 reads (42%) | catalogued as COSV54876273, COSV54893537; called by mutect2, pindel, varscan2
- SPIRE2 | c.1763G>A p.C588Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778892449; called by muse, mutect2, varscan2
- ST18 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV52500652, COSV99389190; called by muse, mutect2
- ZFYVE26 | c.5271G>C p.E1757D | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.09); catalogued as rs778095161; called by muse, mutect2, varscan2
- ABCF1 | c.2303A>T p.E768V (on ENST00000326195 / NM_001025091.2; = p.E730V on NM_001090.3) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BFSP1 | c.1523G>A p.G508D | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DPYSL2 | c.1462C>G p.L488V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- DYRK1B | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- EDRF1 | c.1446A>C p.R482S (on ENST00000356792 / NM_001202438.2; = p.R448S on NM_015608.2) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GPR137 | c.423_449del p.A142_F150del | In Frame Del (DEL) | VAF 24/101 reads (24%) | called by mutect2, pindel
- GREB1 | c.868A>G p.N290D | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- KANSL2 | c.517A>G p.I173V | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCOR1 | c.5910C>G p.S1970R | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHYHIP | c.452A>C p.H151P | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SEM1 | c.62A>C p.E21A | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SERPINA9 | c.943T>A p.S315T | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF567 | c.99T>A p.D33E (on ENST00000536254 / NM_001322913.1; = p.D2E on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ACAN | c.987C>T p.Y329= | Silent (SNP) | VAF 37/116 reads (32%) | called by muse, mutect2, varscan2
- BLNK | c.1230C>T p.G410= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- CLPB | c.1119C>T p.H373= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs774851760; called by muse, mutect2, varscan2
- IGHV4-59 | c.30G>A p.L10= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1206053852; called by muse, mutect2, varscan2
- KAT6A | c.1518C>T p.V506= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- SLC6A12 | c.960C>T p.I320= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs140669203; called by muse, mutect2, varscan2
- SLC7A6 | c.157C>T p.L53= | Silent (SNP) | VAF 73/157 reads (46%) | called by muse, mutect2, varscan2
- ZNF324B | c.750T>G p.L250= | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- ATP2B3 | c.3342+4591C>T | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2
- MFSD14A | c.*1C>A | 3'UTR (SNP) | VAF 6/26 reads (23%) | catalogued as rs575581500, COSV54927751; called by muse, mutect2, varscan2
- TAOK2 | chr16:29990835 C>G | 3'Flank (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- XIRP2 | c.*475_*477del | 3'UTR (DEL) | VAF 41/112 reads (37%) | catalogued as rs752976492; called by pindel, varscan2
